Somatic mutation profile of tumor specimen 0DOQG6 from CCDI case PBCACY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain stem; Age at diagnosis: 21.0 years (7,681 days).
Specimen 0DOQG6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d277fff3-f5e0-4660-a49d-388d42804da5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOQGL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aa1613c-d358-4440-b9c9-54725ff831eb

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 2, 5'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 219/648 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 709/975 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 30/658 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- CLDN16 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 466/1574 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs200023201; called by muse, mutect2, varscan2
- DNAH10 | c.6544G>A p.V2182I (on ENST00000409039; = p.V2121I on NM_207437.3) | Missense Mutation (SNP) | VAF 30/1014 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs771895256, COSV68987865; called by muse, mutect2
- ITPR2 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 309/1026 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1435703432, COSV67266207; called by muse, mutect2, varscan2
- KCNB2 | c.2436C>A p.D812E | Missense Mutation (SNP) | VAF 201/995 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs1456673547, COSV73053168; called by muse, mutect2, varscan2
- KCNB2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 200/989 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs866902223, COSV73051791; called by muse, mutect2, varscan2
- LRRC63 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 66/1648 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1341558582, COSV66512242; called by muse, mutect2
- MORC1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 269/834 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs114679116, COSV51725480; called by muse, mutect2, varscan2
- PKNOX2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 203/701 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs745698010; called by muse, mutect2, varscan2
- PTH2R | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 451/1375 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761834541, COSV55916480, COSV99782746; called by muse, mutect2, varscan2
- TTN | c.74177A>G p.Y24726C (on ENST00000591111; = p.Y17302C on NM_003319.4) | Missense Mutation (SNP) | VAF 46/1854 reads (2%) | PolyPhen possibly damaging (0.847); catalogued as rs1317943530; called by muse, mutect2
- ATRX | c.6436C>T p.Q2146* | Nonsense Mutation (SNP) | VAF 568/823 reads (69%) | called by muse, mutect2, varscan2
- CCDC173 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 532/1646 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DSC2 | c.1243G>T p.G415* | Nonsense Mutation (SNP) | VAF 47/1235 reads (4%) | called by muse, mutect2
- MYH15 | c.2517G>T p.W839C | Missense Mutation (SNP) | VAF 582/1758 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- PER2 | c.206T>G p.V69G | Missense Mutation (SNP) | VAF 293/767 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CCNT1 | c.2103A>G p.R701= | Silent (SNP) | VAF 36/882 reads (4%) | called by muse, mutect2
- RAD21 | c.1895A>G p.*632= | Silent (SNP) | VAF 54/1059 reads (5%) | catalogued as rs1315026169; called by muse, mutect2
- RHPN2 | c.1226-59G>A | Intron (SNP) | VAF 76/218 reads (35%) | called by muse, mutect2, varscan2
- SLC6A11 | chr3:10816213 G>T | 5'Flank (SNP) | VAF 177/335 reads (53%) | called by muse, mutect2, varscan2
- SSPOP | n.9275G>A | RNA (SNP) | VAF 287/841 reads (34%) | catalogued as rs150092603, COSV100948203, COSV65126999; called by muse, mutect2, varscan2
